Somatic mutation profile of tumor specimen TCGA-BB-A5HZ-01A (aliquot TCGA-BB-A5HZ-01A-21D-A28R-08) from TCGA case TCGA-BB-A5HZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 65.5 years (23,906 days).
Specimen TCGA-BB-A5HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 001f090e-6542-4644-982c-db58151abfd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-A5HZ-10A (Blood Derived Normal), aliquot TCGA-BB-A5HZ-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfff9dab-4ae9-4c87-9582-58018d620b97

The open-access MAF lists 87 somatic variants for this specimen: 59 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 26, Frame Shift Del 6, Nonsense Mutation 4, In Frame Del 2, Splice Region 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs879253911, CM941328, COSV52694461, COSV52816009, COSV53014483, COSV53470757; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2383G>A p.V795M (on ENST00000614293; = p.V765M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs768803828, COSV55805644; called by muse, mutect2, varscan2
- ACTL9 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1555753452, COSV61005115; called by muse, mutect2
- ADAMTS14 | c.2401C>G p.P801A | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100941855; called by muse, mutect2
- ADCY1 | c.1106A>T p.H369L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV99812894; called by muse, mutect2, varscan2
- AKAP6 | c.5430G>T p.L1810F | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55220631; called by muse, mutect2, varscan2
- ARFGEF2 | c.2278C>A p.Q760K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.694); catalogued as rs763256205, COSV100904475; called by muse, mutect2, varscan2
- ATF1 | c.33G>C p.E11D | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.935); catalogued as COSV100016250; called by muse, mutect2, varscan2
- AVPR1A | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100146911; called by muse, mutect2, varscan2
- CCDC88B | c.1470G>C p.E490D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100105826, COSV100105921; called by muse, mutect2, varscan2
- CDC20B | c.688A>T p.N230Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99697405; called by muse, mutect2, varscan2
- CNTNAP5 | c.2393A>T p.E798V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101444210; called by muse, mutect2, varscan2
- DICER1 | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100602549, COSV100602570; called by muse, mutect2, varscan2
- EP400 | c.2947T>C p.C983R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as COSV100202255; called by muse, mutect2, varscan2
- ERICH6 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1247965774, COSV99901986; called by muse, mutect2, varscan2
- IGLON5 | c.133del p.C45Vfs*16 | Frame Shift Del (DEL) | VAF 31/158 reads (20%) | catalogued as COSV54535034; called by mutect2, pindel, varscan2
- KANK4 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 104/207 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as rs867539814, COSV100587710; called by muse, mutect2, varscan2
- KIR2DL1 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.67); catalogued as COSV52412156, COSV52413245; called by muse, mutect2, varscan2
- MECOM | c.1229G>A p.G410D (on ENST00000468789 / NM_001105078.4; = p.G598D on NM_004991.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99245401; called by muse, mutect2, varscan2
- MED13 | c.4174C>T p.L1392F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101181391; called by muse, mutect2, varscan2
- MMP16 | c.802T>C p.Y268H | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99690377; called by muse, mutect2, varscan2
- MRGPRX2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs779903448, COSV61674935; called by muse, mutect2, varscan2
- MRTO4 | c.645C>G p.F215L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100367538; called by muse, mutect2, varscan2
- MTTP | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV55503908, COSV99645574; called by muse, mutect2, varscan2
- NABP1 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs138402221, COSV100323109; called by muse, mutect2, varscan2
- NEURL2 | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99510139; called by muse, mutect2, varscan2
- PATE1 | c.77G>T p.R26I | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.277); catalogued as COSV59824348; called by muse, mutect2
- PKP1 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99825702; called by muse, mutect2, varscan2
- PLEKHH2 | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 39/150 reads (26%) | catalogued as COSV56760418; called by muse, mutect2, varscan2
- POU2F2 | c.991G>A p.A331T (on ENST00000526816 / NM_001207025.3; = p.A315T on NM_002698.5) | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1310990639, COSV100657535; called by muse, mutect2, varscan2
- PSG3 | c.684T>A p.S228R | Missense Mutation (SNP) | VAF 149/659 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100549259; called by muse, mutect2, varscan2
- RESF1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.021); catalogued as rs1255277097, COSV57019887; called by muse, mutect2, varscan2
- RHOA | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as COSV101371162; called by muse, mutect2
- SNTG2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs767574929, COSV100422352, COSV100424801; called by muse, mutect2
- SP3 | c.207A>G p.I69M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100022227; called by muse, mutect2, varscan2
- SPAG7 | c.375G>C p.E125D | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); catalogued as COSV99236812; called by muse, mutect2
- SPATA18 | c.1353C>T p.C451= | Splice Region (SNP) | VAF 29/140 reads (21%) | catalogued as rs760300426, COSV99731257; called by muse, mutect2, varscan2
- SPEG | c.3668A>T p.H1223L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100405625; called by muse, mutect2, varscan2
- SPG11 | c.3801G>T p.K1267N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV99969625; called by muse, mutect2
- TACR1 | c.571A>C p.I191L | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100538173; called by muse, mutect2, varscan2
- TIAM1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV99738865; called by muse, mutect2, varscan2
- TMEM117 | c.1329C>A p.S443R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99863681; called by muse, mutect2, varscan2
- TRAF6 | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs759661560, COSV100777742; called by muse, mutect2, varscan2
- UBE3D | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV52753032, COSV52753354, COSV99389030; called by muse, mutect2, varscan2
- WNK4 | c.3325G>C p.V1109L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99891463; called by muse, mutect2, varscan2
- ZNF280A | c.893T>G p.F298C | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131239; called by muse, mutect2, varscan2
- ZNF491 | c.536G>T p.R179I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.562); catalogued as COSV60058903; called by muse, mutect2, varscan2
- ZNF518A | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 23/247 reads (9%) | catalogued as COSV100283737; called by muse, mutect2
- ZNF646 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100336912; called by muse, mutect2, varscan2
- BHLHE41 | c.824del p.P275Rfs*6 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- IGLV3-32 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSD1 | c.3283_3293del p.G1095Kfs*2 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- NSD1 | c.3872dup p.F1292Ifs*4 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- OR2A5 | c.899_912del p.A300Vfs*18 | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | called by mutect2, pindel
- RNLS | c.573_575del p.S192del | In Frame Del (DEL) | VAF 13/72 reads (18%) | called by pindel, varscan2
- ROCK1 | c.603_609del p.D202Cfs*9 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- TBX3 | c.635_637del p.N212del | In Frame Del (DEL) | VAF 24/118 reads (20%) | called by pindel, varscan2
- YLPM1 | c.812del p.N271Tfs*18 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.2454A>G p.E818= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV99784445; called by muse, mutect2, varscan2
- ARHGAP28 | c.1701C>T p.R567= (on ENST00000383472 / NM_001366230.1; = p.R408= on NM_001010000.3) | Silent (SNP) | VAF 82/287 reads (29%) | catalogued as COSV51641925, COSV99151432; called by muse, mutect2, varscan2
- CFAP58 | c.1320G>A p.K440= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as COSV100459122; called by muse, mutect2, varscan2
- EPS8 | c.1077C>T p.H359= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99843674; called by muse, mutect2, varscan2
- EVPL | c.3501G>A p.A1167= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs140332207; called by muse, mutect2, varscan2
- FCGBP | c.1296C>T p.C432= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs762516043; called by muse, mutect2, varscan2
- H2AC15 | c.114C>T p.G38= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV100357116; called by muse, mutect2, varscan2
- H3C1 | c.321C>T p.D107= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs759148889, COSV99772201; called by muse, mutect2, varscan2
- MUC2 | c.177C>T p.C59= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs371848793; called by muse, mutect2
- NME7 | c.531A>G p.G177= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100891182; called by muse, mutect2, varscan2
- NPAS4 | c.489C>T p.G163= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV60649875; called by muse, mutect2, varscan2
- OR52B6 | c.399C>A p.V133= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as rs1177436926, COSV100798543, COSV61448206; called by muse, mutect2, varscan2
- OXTR | c.549C>T p.G183= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs750004965, COSV100373050; called by muse, mutect2, varscan2
- PCDHGA8 | c.2280C>T p.T760= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV99546811; called by muse, mutect2, varscan2
- PCDHGC4 | c.1020G>T p.L340= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV99342307; called by muse, mutect2, varscan2
- PCYOX1L | c.1200G>A p.K400= | Silent (SNP) | VAF 28/203 reads (14%) | catalogued as rs1561704950, COSV99199287; called by muse, mutect2, varscan2
- PLIN4 | c.1707C>A p.V569= (on ENST00000301286; = p.V584= on NM_001367868.2) | Silent (SNP) | VAF 98/258 reads (38%) | catalogued as rs1349014057, COSV100014105; called by muse, mutect2, varscan2
- RYR1 | c.5385G>A p.P1795= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs772422894, COSV100617001; called by muse, mutect2, varscan2
- SCFD1 | c.1050A>T p.A350= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100356572; called by muse, mutect2, varscan2
- SFN | c.507C>T p.R169= | Silent (SNP) | VAF 61/191 reads (32%) | catalogued as COSV100212881; called by muse, mutect2, varscan2
- SLITRK4 | c.2025C>A p.T675= | Silent (SNP) | VAF 55/114 reads (48%) | catalogued as COSV100567520, COSV62025487; called by muse, mutect2, varscan2
- SPRED2 | c.108C>T p.G36= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs1360350056, COSV100710018; called by muse, mutect2, varscan2
- TLR4 | c.1359C>T p.D453= (on ENST00000355622 / NM_138554.5; = p.D413= on NM_003266.4) | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV100842859; called by muse, mutect2, varscan2
- TPST1 | c.876G>A p.K292= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs1476975885, COSV100507363; called by muse, mutect2, varscan2
- TSHZ3 | c.1290C>T p.V430= | Silent (SNP) | VAF 40/174 reads (23%) | catalogued as rs1287127275, COSV53666238, COSV99552717; called by muse, mutect2, varscan2
- TWSG1 | c.162C>G p.S54= | Silent (SNP) | VAF 84/151 reads (56%) | catalogued as COSV100039551; called by muse, mutect2, varscan2
- PGAP2 | c.165+6062T>A | Intron (SNP) | VAF 24/78 reads (31%) | catalogued as COSV99544597; called by muse, mutect2, varscan2
- SNORD115-2 | n.5C>A | RNA (SNP) | VAF 48/222 reads (22%) | called by muse, mutect2, varscan2
